Somatic mutation profile of tumor specimen C3L-00943-01 (aliquot CPT0086090009) from CPTAC case C3L-00943, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 63.1 years (23,047 days).
Specimen C3L-00943-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b0fa0c9-04f1-4e18-94e2-66172e5b1f68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00943-31 (Blood Derived Normal), aliquot CPT0086140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d378f1a-b9ae-4323-aead-4317e01b29f8

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Nonsense Mutation 4, Frame Shift Del 1, Intron 1, In Frame Del 1, Splice Region 1, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 52/347 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PTEN | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 49/384 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs121909223, CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 36/219 reads (16%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- BMP7 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs202153108; called by muse, mutect2, varscan2
- CRTC1 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs565862606; called by muse, mutect2, varscan2
- LNPEP | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs778308598; called by muse, mutect2
- LRRN4 | c.1847C>A p.A616E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs767237215, COSV66644702; called by muse, mutect2
- OTUD6A | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs1441217498, COSV100611017, COSV57973537; called by muse, mutect2, varscan2
- PTEN | c.165G>T p.R55S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64296734, COSV64301456; called by muse, mutect2, varscan2
- RYR2 | c.6017A>G p.H2006R | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1553528609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC27A6 | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as rs754916870, COSV52479245, COSV99322511; called by muse, mutect2
- UNC45A | c.830G>C p.R277P | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV67816368; called by muse, mutect2
- USP25 | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs780876310, COSV99584454; called by muse, mutect2, varscan2
- ZBED9 | c.814C>A p.R272S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.046); catalogued as COSV71729539, COSV71729716; called by muse, mutect2, varscan2
- ADGB | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARID1A | c.5623_5663del p.P1875Tfs*12 | Frame Shift Del (DEL) | VAF 20/205 reads (10%) | called by mutect2, pindel
- ATP10A | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCF | c.935dup p.H312Qfs*3 | Frame Shift Ins (INS) | VAF 17/128 reads (13%) | called by mutect2, pindel
- DLX3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2AK4 | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- GTF2E2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 19/176 reads (11%) | called by muse, mutect2, varscan2
- GTF3C3 | c.403A>T p.M135L | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP1B | c.4532G>T p.G1511V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MRPL15 | c.14T>G p.L5W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NDST1 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 65/412 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- NUP214 | c.6216G>A p.G2072= | Splice Region (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1729_1745+1del | In Frame Del (DEL) | VAF 22/115 reads (19%) | called by mutect2, pindel, varscan2
- PKP2 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRSS8 | c.191A>C p.Y64S | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- REV3L | c.8890C>T p.Q2964* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2
- TYSND1 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- USP19 | c.2111G>A p.S704N | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR24 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM83G | c.804C>T p.C268= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs752370159, COSV100525575; called by muse, mutect2, varscan2
- KRT26 | c.678G>A p.E226= | Silent (SNP) | VAF 29/229 reads (13%) | catalogued as rs1165806979; called by muse, mutect2, varscan2
- L3MBTL2 | c.1047C>T p.I349= | Silent (SNP) | VAF 9/206 reads (4%) | catalogued as rs1569149332; called by muse, mutect2
- PCLO | c.13629G>A p.A4543= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs771864365, COSV100426565, COSV100439248; called by muse, mutect2, varscan2
- SYT17 | c.756G>A p.Q252= | Silent (SNP) | VAF 34/209 reads (16%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444488 G>A | 5'Flank (SNP) | VAF 9/160 reads (6%) | catalogued as rs1164358590; called by muse, mutect2
- KRT6C | c.-25C>G | 5'UTR (SNP) | VAF 29/274 reads (11%) | called by muse, mutect2, varscan2
- PLD1 | c.2882+673C>T | Intron (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*615C>T | 3'UTR (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
